Somatic mutation profile of tumor specimen TCGA-G4-6314-01A (aliquot TCGA-G4-6314-01A-11D-1719-10) from TCGA case TCGA-G4-6314, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 76.5 years (27,958 days).
Specimen TCGA-G4-6314-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65d0654e-6c4a-4a72-b25d-04e91e58c3c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6314-10A (Blood Derived Normal), aliquot TCGA-G4-6314-10A-01D-1720-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65141ffd-5baa-42e9-bc78-d4c8ddef2722

The open-access MAF lists 155 somatic variants for this specimen: 115 protein-altering or splice-affecting, 33 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 33, Nonsense Mutation 10, Intron 4, Frame Shift Del 2, RNA 2, Frame Shift Ins 1, 5'UTR 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4473dup p.A1492Cfs*22 | Frame Shift Ins (INS) | VAF 35/107 reads (33%) | catalogued as rs398123122, COSV57345867, COSV99964369, COSV99971373; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 64/114 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 68/118 reads (58%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1789G>A p.V597I | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs199931362, COSV55952252; called by muse, mutect2, varscan2
- ACTC1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as rs1179943060, COSV51757242, COSV51759304; called by muse, mutect2, varscan2
- ADAM33 | c.2286C>G p.H762Q | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV62934935; called by muse, mutect2, varscan2
- ADGRB2 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.16); catalogued as rs773280182, COSV99926956; called by muse, mutect2, varscan2
- ADGRG2 | c.1435A>G p.T479A (on ENST00000379869 / NM_001079858.3; = p.T476A on NM_005756.4) | Missense Mutation (SNP) | VAF 108/215 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV61339238; called by muse, mutect2, varscan2
- ANKRD52 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs773443613, COSV99921074; called by muse, mutect2, varscan2
- APBB1 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 67/450 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs370357442, COSV54980818; called by muse, mutect2, varscan2
- ARHGAP29 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs140877322; called by muse, mutect2, varscan2
- ATCAY | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1300743591, COSV56656208; called by muse, mutect2, varscan2
- BCAS1 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 80/269 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.558); catalogued as COSV65086279; called by muse, mutect2, varscan2
- BRINP2 | c.1881G>A p.W627* | Nonsense Mutation (SNP) | VAF 21/101 reads (21%) | catalogued as COSV100838479; called by muse, mutect2, varscan2
- CD163 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.811); catalogued as COSV63132714; called by muse, mutect2, varscan2
- CDH22 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1342674990, COSV64837366; called by muse, mutect2, varscan2
- CENPQ | c.538A>C p.K180Q | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT tolerated (0.86); PolyPhen benign (0.086); catalogued as COSV59921259; called by muse, mutect2, varscan2
- CEP85L | c.2338C>T p.R780* | Nonsense Mutation (SNP) | VAF 33/266 reads (12%) | catalogued as COSV63823503; called by muse, mutect2, varscan2
- CFAP206 | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV51532910; called by muse, mutect2
- CLDN6 | c.94G>T p.V32L | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV58509567; called by muse, mutect2, varscan2
- DAO | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs749872143, COSV57322593; called by muse, mutect2, varscan2
- DBR1 | c.1062G>T p.Q354H | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV53429908; called by muse, mutect2, varscan2
- DHX38 | c.2992C>T p.R998W | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51698151; called by muse, mutect2, varscan2
- EIF2AK4 | c.3886G>C p.E1296Q | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55468744; called by muse, mutect2, varscan2
- EPHA1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs756665403, COSV51971665; called by muse, mutect2, varscan2
- EPS8L2 | c.2006del p.V669Gfs*33 | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | catalogued as COSV59348020; called by mutect2, pindel, varscan2
- EYA4 | c.1241G>A p.R414H (on ENST00000531901 / NM_001301013.1; = p.R408H on NM_004100.5) | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs760787542, COSV62047993, COSV62049072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAAH | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs775398610, COSV54543985; called by muse, mutect2, varscan2
- FBN2 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as COSV52515543; called by muse, mutect2, varscan2
- FGD1 | c.1448C>T p.T483I | Missense Mutation (SNP) | VAF 87/186 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV64308776; called by muse, mutect2, varscan2
- FLG | c.10001G>A p.G3334E | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.895); catalogued as rs747072444, COSV64242380; called by muse, mutect2, varscan2
- FLNA | c.2839G>A p.V947I | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT tolerated (0.49); PolyPhen benign (0.063); catalogued as rs782239678, COSV61043731; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- FRMPD4 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs370344979, COSV66213661; called by muse, mutect2, varscan2
- GABRA3 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 55/127 reads (43%) | catalogued as rs754301642, COSV64795089; called by muse, mutect2, varscan2
- GABRG3 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 82/220 reads (37%) | catalogued as COSV61519065, COSV61523357; called by muse, mutect2, varscan2
- GLI1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs369404558; called by muse, mutect2, varscan2
- GRM1 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV51154276; called by muse, mutect2, varscan2
- GSDME | c.70A>G p.N24D | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.412); catalogued as COSV61651776; called by muse, mutect2, varscan2
- HGF | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1351384112, COSV55944955; called by muse, mutect2, varscan2
- IGHG3 | c.1335del p.A446Pfs*101 | Frame Shift Del (DEL) | VAF 45/176 reads (26%) | catalogued as rs760464364; called by mutect2, pindel, varscan2
- IQCA1 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs563978762, COSV54502861; called by muse, mutect2, varscan2
- IRS2 | c.3397G>A p.A1133T | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65478911; called by muse, varscan2
- JARID2 | c.3227C>G p.P1076R | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.168); catalogued as COSV59189805; called by muse, mutect2, varscan2
- JRKL | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53592512; called by muse, mutect2, varscan2
- KCNA5 | c.613C>G p.L205V | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV52906015; called by muse, mutect2, varscan2
- KCNQ2 | c.2555C>T p.P852L (on ENST00000359125 / NM_172107.4; = p.P824L on NM_004518.6) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.69); catalogued as rs745508762, COSV100609924, COSV100610594; ClinVar: uncertain significance; called by muse, mutect2
- KCNS1 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1285420387, COSV60260192; called by muse, mutect2, varscan2
- KIF26B | c.3742G>A p.V1248I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs371194278; called by muse, mutect2, varscan2
- KIF2B | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1275459238, COSV52130460; called by muse, mutect2
- KMT2B | c.4635G>T p.Q1545H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV55861734; called by muse, mutect2, varscan2
- LRP4 | c.2403G>T p.K801N | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.334); catalogued as COSV66136014; called by muse, mutect2, varscan2
- MAP4K1 | c.889G>C p.G297R | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as rs1322359494, COSV67710527; called by muse, mutect2, varscan2
- MATN2 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 55/360 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs766623442, COSV54711822; called by muse, mutect2, varscan2
- MBD3L2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1274828548, COSV100421475; called by mutect2, varscan2
- METTL3 | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as rs1031213111, COSV52969079; called by muse, mutect2, varscan2
- MRPS27 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV54650889; called by muse, mutect2, varscan2
- MS4A5 | c.101C>G p.S34* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as COSV55741003; called by muse, mutect2, varscan2
- MTMR3 | c.479G>T p.R160M | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV60304683; called by muse, mutect2
- NAV2 | c.7061C>T p.S2354L (on ENST00000396087 / NM_001244963.2; = p.S2295L on NM_145117.5) | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs753133443, COSV60659569; called by muse, mutect2, varscan2
- NCAM1 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs576548045, COSV57516984; called by muse, mutect2, varscan2
- NCLN | c.802T>A p.Y268N | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV55742679; called by muse, mutect2, varscan2
- NEUROG3 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 158/406 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.19); catalogued as rs1481494516, COSV54342979; called by muse, mutect2, varscan2
- NR1I2 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100561730; called by muse, mutect2, varscan2
- NTRK3 | c.2286G>T p.E762D (on ENST00000360948 / NM_001012338.2; = p.E748D on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1361372348, COSV62305415; called by muse, mutect2, varscan2
- OBSCN | c.23459A>C p.K7820T | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV62431532; called by muse, mutect2, varscan2
- OR13C3 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1031639007, COSV66165873; called by muse, mutect2, varscan2
- OR2J3 | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 154/459 reads (34%) | catalogued as rs780463918, COSV65848597; called by muse, mutect2, varscan2
- OVCH2 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs765472882, COSV71952835; called by muse, mutect2, varscan2
- PCDH1 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV54614304; called by muse, mutect2, varscan2
- PLG | c.1987C>T p.R663* | Nonsense Mutation (SNP) | VAF 47/195 reads (24%) | catalogued as rs752522150, CM154959, COSV57513850; called by muse, mutect2, varscan2
- PLXNA3 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63754180; called by muse, mutect2, varscan2
- PLXNA3 | c.149T>G p.V50G | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63754182; called by muse, mutect2, varscan2
- PNPLA5 | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as rs751134085, COSV53374145; called by muse, mutect2, varscan2
- POLR3E | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55400903; called by muse, mutect2, varscan2
- PPP1R16A | c.1367T>C p.L456P | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99477863; called by muse, mutect2, varscan2
- PRF1 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV64615019; called by muse, mutect2, varscan2
- PRR23B | c.628T>C p.S210P | Missense Mutation (SNP) | VAF 18/273 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs777413573, COSV100272233; called by muse, mutect2
- PTHLH | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 114/220 reads (52%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1485377870, COSV52367904; called by muse, mutect2, varscan2
- QARS1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs957599864, COSV60274584; called by muse, mutect2, varscan2
- RANBP2 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 217/1114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51701660, COSV99311378; called by muse, mutect2, varscan2
- RAPGEF4 | c.1523T>A p.I508N | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs755235277, COSV51381498; called by muse, mutect2, varscan2
- RHOD | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100448104; called by muse, mutect2
- RNF17 | c.3052C>G p.L1018V | Missense Mutation (SNP) | VAF 79/328 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV55041115; called by muse, mutect2, varscan2
- ROS1 | c.1342C>G p.R448G | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV63859202; called by muse, mutect2, varscan2
- RPGRIP1L | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 330/454 reads (73%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.784); catalogued as COSV50907450; called by muse, mutect2, varscan2
- RYR2 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV63687410; called by muse, mutect2, varscan2
- RYR2 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as rs1470689668, COSV63665957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN8A | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs375480171; called by muse, mutect2, varscan2
- SETD2 | c.7624G>C p.E2542Q | Missense Mutation (SNP) | VAF 61/396 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57438486, COSV57438931, COSV57446878; called by muse, mutect2, varscan2
- SETX | c.7100+2del p.X2367_splice | Splice Site (DEL) | VAF 83/225 reads (37%) | catalogued as CS139796; called by mutect2, pindel, varscan2
- SFTPC | c.350C>G p.P117R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.956); catalogued as COSV59345629; called by muse, mutect2, varscan2
- SHPK | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs1352243632, COSV56649150; called by muse, mutect2, varscan2
- SIGLEC8 | c.346A>T p.K116* | Nonsense Mutation (SNP) | VAF 103/512 reads (20%) | catalogued as COSV58474006; called by muse, mutect2, varscan2
- SLC24A3 | c.726A>C p.L242F | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100043227; called by muse, mutect2, varscan2
- SLC6A13 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV58257434; called by muse, mutect2, varscan2
- SOX9 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1373080436, COSV55424597; called by muse, mutect2, varscan2
- SPTBN1 | c.6911C>T p.S2304F | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs1231763718, COSV63339519; called by muse, mutect2, varscan2
- SRSF4 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65694721; called by muse, mutect2, varscan2
- SUPT3H | c.907C>T p.R303C (on ENST00000371460 / NM_181356.3; = p.R292C on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs762070625, COSV60933054, COSV60939853; called by muse, mutect2, varscan2
- TCEAL6 | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 265/525 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as COSV65653946; called by muse, varscan2
- TCHH | c.398C>G p.P133R | Missense Mutation (SNP) | VAF 149/680 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV64275066, COSV64276227; called by muse, mutect2, varscan2
- TENT5C | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 96/489 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs750792861, COSV65616442; called by muse, mutect2, varscan2
- TLR5 | c.2207C>G p.P736R | Missense Mutation (SNP) | VAF 133/352 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60559242; called by muse, mutect2, varscan2
- TMEM64 | c.976T>C p.F326L | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV69127824; called by muse, mutect2, varscan2
- TPSG1 | c.243C>T p.S81= | Splice Region (SNP) | VAF 11/19 reads (58%) | catalogued as rs777408938, COSV52354844; called by muse, mutect2, varscan2
- TRIML1 | c.1025A>G p.Y342C | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV60194457; called by muse, mutect2, varscan2
- TTK | c.2411G>C p.G804A | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.08); catalogued as COSV57883192; called by muse, mutect2, varscan2
- TTLL8 | c.1388G>T p.R463L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56722051, COSV99838287; called by muse, mutect2, varscan2
- UBE2Q1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 69/353 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as rs754369992, COSV52724786; called by muse, mutect2, varscan2
- UNC79 | c.542C>T p.T181M (on ENST00000393151 / NM_001346218.2; = p.T4M on NM_020818.5) | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1374387491, COSV56389499; called by muse, mutect2, varscan2
- USP38 | c.3029G>A p.R1010Q | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs374019822; called by muse, mutect2, varscan2
- ZMYND8 | c.1325C>T p.T442M (on ENST00000311275 / NM_001363741.2; = p.T462M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1373808840, COSV53688286; called by muse, mutect2, varscan2
- ZNF569 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV57595683, COSV57596841; called by muse, mutect2, varscan2
- ZNFX1 | c.4262G>A p.G1421D | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV65597977; called by muse, mutect2, varscan2
- ASRGL1 | c.603G>A p.P201= | Silent (SNP) | VAF 44/139 reads (32%) | catalogued as rs767383304, COSV57126363; called by muse, mutect2, varscan2
- ATP8A2 | c.3351G>A p.A1117= | Silent (SNP) | VAF 50/252 reads (20%) | catalogued as rs372429577; called by muse, mutect2, varscan2
- C16orf54 | c.147C>T p.T49= | Silent (SNP) | VAF 59/139 reads (42%) | catalogued as rs765609481, COSV61476798; called by muse, mutect2, varscan2
- CACNA1G | c.1209G>A p.Q403= | Silent (SNP) | VAF 34/269 reads (13%) | catalogued as COSV61728511; called by muse, mutect2, varscan2
- CACNG2 | c.90C>T p.T30= | Silent (SNP) | VAF 233/637 reads (37%) | catalogued as COSV55635336; called by muse, mutect2, varscan2
- CLCA4 | c.1842C>T p.Y614= | Silent (SNP) | VAF 93/263 reads (35%) | catalogued as rs372874690; called by muse, mutect2, varscan2
- CLDN19 | c.105C>T p.Y35= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs760544476, COSV56419471; called by muse, mutect2, varscan2
- DCLK1 | c.1233G>C p.S411= | Silent (SNP) | VAF 69/143 reads (48%) | catalogued as COSV55176582, COSV55188156; called by muse, mutect2, varscan2
- ELOA2 | c.2115C>T p.L705= | Silent (SNP) | VAF 60/117 reads (51%) | catalogued as COSV55299750; called by muse, mutect2, varscan2
- GRM7 | c.591C>T p.R197= | Silent (SNP) | VAF 57/163 reads (35%) | catalogued as rs201728113, COSV63144610; called by muse, mutect2, varscan2
- HECW1 | c.174C>T p.H58= | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as rs906767913, COSV67820621, COSV67827293; called by muse, mutect2, varscan2
- HROB | c.672C>T p.S224= | Silent (SNP) | VAF 54/173 reads (31%) | catalogued as rs779804885, COSV99809421; called by muse, mutect2, varscan2
- IBA57 | c.282G>A p.A94= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV64511128; called by muse, mutect2, varscan2
- KHDC3L | c.513G>A p.P171= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs1376020646, COSV64863253; called by muse, mutect2
- MAGEB10 | c.531C>T p.I177= | Silent (SNP) | VAF 63/127 reads (50%) | catalogued as COSV63311431; called by muse, mutect2, varscan2
- MYBL2 | c.1356G>A p.S452= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as rs1005184780, COSV53827685; called by muse, mutect2, varscan2
- NDUFS7 | c.21T>A p.P7= | Silent (SNP) | VAF 74/174 reads (43%) | catalogued as COSV52039336; called by muse, mutect2, varscan2
- OPN4 | c.1050C>T p.Y350= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as rs751996931, COSV54116644; called by muse, mutect2, varscan2
- OR2T27 | c.570G>A p.T190= | Silent (SNP) | VAF 14/210 reads (7%) | catalogued as rs1368322208, COSV61281026; called by muse, mutect2
- PCDHGA6 | c.891G>A p.L297= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV53955446; called by muse, mutect2, varscan2
- PDZRN3 | c.2772G>A p.K924= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs1389609520, COSV55201196; called by muse, mutect2, varscan2
- R3HDML | c.348C>T p.Y116= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as rs571680930, COSV53836116; called by muse, mutect2, varscan2
- SCAP | c.2140C>T p.L714= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV55561664; called by muse, mutect2, varscan2
- SGTB | c.39T>C p.R13= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV66765969; called by muse, mutect2, varscan2
- SIGLEC1 | c.1764G>A p.S588= | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as rs372490374; called by muse, mutect2, varscan2
- SLC36A2 | c.66G>A p.S22= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as rs757660921, COSV58863435; called by muse, mutect2, varscan2
- SRPK3 | c.672C>T p.D224= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as rs1231713456, COSV54207824; called by muse, mutect2, varscan2
- TCF23 | c.321G>A p.P107= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as rs1002946243, COSV56078413; called by muse, mutect2, varscan2
- TMEM104 | c.1293C>T p.T431= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs367939276; called by muse, mutect2, varscan2
- TNS1 | c.708C>T p.I236= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as rs1364036682, COSV50705200; called by muse, mutect2, varscan2
- TRPS1 | c.3501G>A p.A1167= (on ENST00000220888 / NM_001330599.2; = p.A1180= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/284 reads (15%) | catalogued as rs764387571, COSV55227769, COSV55261126, COSV99635564; called by muse, mutect2, varscan2
- TTN | c.49428C>A p.V16476= (on ENST00000591111; = p.V9052= on NM_003319.4) | Silent (SNP) | VAF 44/164 reads (27%) | catalogued as COSV100611224, COSV60086987; called by muse, mutect2, varscan2
- VPS37C | c.237G>A p.E79= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as rs1463019104, COSV100075344; called by muse, mutect2, varscan2
- KNOP1P1 | n.392C>G | RNA (SNP) | VAF 90/167 reads (54%) | called by muse, mutect2, varscan2
- MGA | c.4435-127G>A | Intron (SNP) | VAF 18/79 reads (23%) | catalogued as rs1341800105; called by muse, mutect2, varscan2
- MIR365A | n.26G>A | RNA (SNP) | VAF 28/163 reads (17%) | called by muse, mutect2, varscan2
- PNLDC1 | c.-1G>A | 5'UTR (SNP) | VAF 24/106 reads (23%) | catalogued as rs748705189, COSV51706248; called by muse, varscan2
- PPP1R12B | c.2863-5338G>T | Intron (SNP) | VAF 19/57 reads (33%) | catalogued as COSV51785243; called by muse, mutect2, varscan2
- THSD4 | c.1016-70105G>A | Intron (SNP) | VAF 2/17 reads (12%) | called by muse, mutect2
- TP53AIP1 | c.141+51G>A | Intron (SNP) | VAF 24/156 reads (15%) | catalogued as rs779018599; called by muse, mutect2, varscan2
